Somatic mutation profile of tumor specimen 0DESU2 from CCDI case PBBRAT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 24.4 years (8,906 days).
Specimen 0DESU2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d31733c4-4a1b-4558-87d6-fabc1041280d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DESU3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bdc7390-5a69-4da0-82e5-728772a6266f

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Splice Region 1, 3'UTR 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 168/418 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, varscan2
- ADGRB1 | c.2488G>A p.V830M | Missense Mutation (SNP) | VAF 227/600 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs376043066; called by muse, varscan2
- DAXX | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 263/736 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs967799519, COSV56470430; called by muse, varscan2
- HS3ST2 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 344/846 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs138024835; called by muse, varscan2
- NCOR2 | c.6398C>T p.A2133V | Missense Mutation (SNP) | VAF 290/726 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62300501; called by muse, varscan2
- TEX13A | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 378/486 reads (78%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100781098; called by muse, varscan2
- COL22A1 | c.2893C>A p.P965T | Missense Mutation (SNP) | VAF 121/642 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); called by muse, varscan2
- FAM131B | c.743A>C p.E248A | Missense Mutation (SNP) | VAF 336/900 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.015); called by muse, varscan2
- RIT1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 380/975 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, varscan2
- SLC17A8 | c.1169A>T p.K390I | Missense Mutation (SNP) | VAF 359/974 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- STEAP1B | c.705+8A>G | Splice Region (SNP) | VAF 174/553 reads (31%) | called by muse, varscan2
- ARFGEF3 | c.6361C>T p.L2121= | Silent (SNP) | VAF 171/513 reads (33%) | called by muse, varscan2
- CA14 | c.915C>T p.L305= | Silent (SNP) | VAF 250/695 reads (36%) | called by muse, varscan2
- CTIF | c.1317G>A p.A439= | Silent (SNP) | VAF 244/655 reads (37%) | catalogued as rs777040402, COSV56482935; called by muse, varscan2
- MUC2 | c.531C>T p.F177= | Silent (SNP) | VAF 186/474 reads (39%) | called by muse, varscan2
- PLCL1 | c.891C>T p.R297= | Silent (SNP) | VAF 453/1161 reads (39%) | catalogued as rs764435154; called by muse, varscan2
- MAPK8 | c.*73T>G | 3'UTR (SNP) | VAF 104/256 reads (41%) | called by muse, varscan2
- PPP1R1A | chr12:54575925 C>A | 3'Flank (SNP) | VAF 138/348 reads (40%) | called by muse, varscan2
- STRN4 | c.2006-45G>T | Intron (SNP) | VAF 68/184 reads (37%) | called by muse, varscan2
